Somatic mutation profile of tumor specimen TARGET-10-PARCAX-09A (aliquot TARGET-10-PARCAX-09A-01D) from TARGET case TARGET-10-PARCAX, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,538 days).
Specimen TARGET-10-PARCAX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 056ddef8-1549-4656-9e01-35620dee390e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARCAX-10A (Blood Derived Normal), aliquot TARGET-10-PARCAX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2ba109c-3e37-418d-9dad-c7f669d36ec8

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 9/103 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- LAMB2 | c.5290C>T p.R1764W | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1231737650, COSV59734700; called by muse, mutect2
- PKLR | c.1457G>A p.R486Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.294); catalogued as rs768210809, CM061899, COSV100712907, COSV61361108; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAB39L | c.276+1G>A p.X92_splice | Splice Site (SNP) | VAF 29/119 reads (24%) | called by muse, mutect2
- SPOCK2 | c.623G>A p.G208E | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSCAML1 | c.3543C>T p.G1181= (on ENST00000321322; = p.G1121= on NM_020693.4) | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as rs145257382; called by muse, mutect2, varscan2
- ZNF804B | c.3636G>A p.T1212= | Silent (SNP) | VAF 46/154 reads (30%) | catalogued as rs775204776; called by muse, mutect2, varscan2
- CNTN5 | c.1580+103G>A | Intron (SNP) | VAF 10/33 reads (30%) | catalogued as rs879092681; called by muse, mutect2, varscan2
